Somatic mutation profile of tumor specimen TARGET-30-PATYMK-01A (aliquot TARGET-30-PATYMK-01A-01D) from TARGET case TARGET-30-PATYMK, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.8 years (1,761 days).
Specimen TARGET-30-PATYMK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 935cccb8-5a3a-4c8d-b3ae-2776b3219d31.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATYMK-10A (Blood Derived Normal), aliquot TARGET-30-PATYMK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdb2a4b6-abab-4462-ae25-c7fb9c7ce6f7

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TPR | c.6556G>C p.A2186P | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100823795, COSV66606650; called by muse, mutect2, varscan2
- ATRX | c.5787-3_5790del p.X1929_splice | Splice Site (DEL) | VAF 18/24 reads (75%) | called by mutect2, varscan2
- LRP6 | c.*719C>T | 3'UTR (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
